Gene-level copy-number profile of tumor specimen TCGA-A2-A1G1-01A from TCGA case TCGA-A2-A1G1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 85.5 years (31,223 days).
Specimen TCGA-A2-A1G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b71535be-881b-4ea5-888a-1f2afbdec4d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1G1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50cfa5b4-1000-4558-aba0-f914553c0ebd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 64; copy number 3: 250; copy number 4: 29,043; copy number 5: 4,300; copy number 6: 19,027; copy number 7: 851; copy number 8: 4,948; copy number 9: 41; copy number 11: 45; copy number 15: 51; copy number 17: 5; copy number 18: 442; copy number 19: 405; copy number 20: 105; copy number 21: 3; copy number 27: 4; copy number 30: 2; copy number 33: 3; copy number 36: 4; copy number 40: 67; copy number 43: 7; copy number 44: 25; copy number 52: 18; copy number 54: 73; copy number 62: 5; copy number 73: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A1G1-01A-21D-A13J-01): tumor purity 0.42, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,335 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:5,072,645–5,363,650, 5 genes, copy number 15: AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1.
- chr8:127,578,473–127,742,951, 4 genes, copy number 27: AC104370.1, AC108925.1, CASC11, MYC.
- chr12:66,767–34,249,958, 850 genes, copy number 18–33 (broad region; genes not listed).
- chr16:68,310,974–68,358,584, 1 gene, copy number 21 (within-gene range 5–21): PRMT7.
- chr16:68,329,387–68,477,570, 7 genes, copy number 21–62: RNU4-30P, SMPD3, AC099521.2, AC099521.3, AC099521.1, Y_RNA, RPL35AP33.
- chr17:37,514,807–39,027,110, 61 genes, copy number 30–54 (within-gene range 4–54) (broad region; genes not listed).
- chr17:39,210,541–41,528,308, 144 genes, copy number 20–54 (broad region; genes not listed).
- chr19:23,304,991–24,163,425, 30 genes, copy number 73: ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr19:29,268,976–31,147,981, 30 genes, copy number 17–52: AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.
- chr19:32,102,088–32,244,083, 4 genes, copy number 36: LINC01782, AC011518.1, AC074139.1, RNA5SP472.
- chr19:33,386,950–33,521,791, 1 gene, copy number 11 (within-gene range 4–11): PEPD.
- chr19:34,788,527–37,248,738, 153 genes, copy number 9–40 (broad region; genes not listed).
- chr19:37,251,885–37,265,535, 1 gene, copy number 9 (within-gene range 4–9): LINC01535.
- chr22:30,693,782–30,907,824, 1 gene, copy number 11 (within-gene range 6–11): OSBP2.
- chr22:30,902,219–31,750,140, 43 genes, copy number 11 (within-gene range 6–11): EIF4HP2, MORC2-AS1, MORC2, TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1, AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3, AC005005.1, MIR3928, RNF185, RNF185-AS1, LIMK2, RNU6-1128P, Y_RNA, PIK3IP1, PIK3IP1-DT, RNA5SP496, PATZ1, LINC01521, RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1, PISD, MIR7109, PRR14L.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
